Surgical pathology report (de-identified scan), TCGA case TCGA-13-A5FU, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-13-A5FU-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3

Cystadenocarcinoma, ~~Stomach~~ NOS
8441/3

Site: C6CF Omentum C48.0

Path Unknown primary
site C80.9

9/2/13

Date of Procedure:

Specimens Submitted:

- 1: Lymph node, left supraclavicular; excision
- 2: Soft tissue, umbilicus; excision
- 3: Omentum; omentectomy
- 4: Lymph nodes, right supradiaphragmatic; excision
- 5: SP: Portion of rectum, pelvic tumor, bilateral adnexa and upper vagina; resection
- 6: Xiphoid; excision
- 7: Soft tissue, left supradiaphragmatic; excision
- 8: Terminal ileum and cecum; ileocelectomy
- 9: Supracolic omentum; excision
- 10: Soft tissue, right diaphragm; excision
- 11: Soft tissue, Morrison's pouch; excision
- 12: Soft tissue, falciform ligament; excision
- 13: Soft tissue, right hepatic artery; excision
- 14: Gallbladder; cholecystectomy
- 15: Soft tissue, gallbladder fossa; excision
- 16: Soft tissue, right liver surface; excision
- 17: Soft tissue, left diaphragm; excision
- 18: Lymph nodes, left external iliac; excision
- 19: Lymph nodes, left obturator; excision
- 20: Lymph nodes, left common iliac; excision
- 21: Lymph nodes, right external iliac; excision
- 22: Lymph nodes, right obturator; excision
- 23: Lymph nodes, right hypogastric; excision
- 24: Soft tissue, sigmoid mesentery; excision
- 25: Soft tissue, left paracolic gutter; excision
- 26: Lymph nodes, small bowel mesentery; excision
- 27: Lymph nodes, aortocaval; excision
- 28: Lymph nodes, left infra renal; excision
- 29: Lymph nodes left para-aortic; excision
- 30: Soft tissue, descending colon mesentery; excision
- 31: Soft tissue, small bowel; excision
- 32: Soft tissue, terminal ileum; excision
- 33: Colon, proximal margin; excision
- 34: Colon, distal margin; excision
- 35: Soft tissue, umbilicus; excision
- 36: Lymph nodes, right inguinal; excision

** Continued on next page **

[page 2 of 4]
37: Lymph nodes, left inguinal; excision

DIAGNOSIS:

1. Lymph node, left supraclavicular; excision:
- Isolated tumor cells present in the vascular space in 1 of 2 lymph nodes, not present on frozen section slide
2. Soft tissue, umbilicus; excision:
- Metastatic high grade serous carcinoma
3. Omentum; omentectomy:
- Metastatic high grade serous carcinoma
4. Lymph nodes, right supradiaphragmatic; excision:
- Metastatic high grade serous carcinoma involving 5 of 6 lymph nodes (5/6)
5. Portion of rectum, pelvic tumor, bilateral adnexa and upper vagina; resection:
- Metastatic high grade serous carcinoma involving rectal serosa and bilateral adnexa
- Low grade squamous intraepithelial lesion of vaginal mucosa (VAIN 1)
6. Xiphoid; excision:
- Benign cartilage
7. Soft tissue, left supradiaphragmatic; excision:
- Metastatic high grade serous carcinoma involving 4 of 4 lymph nodes (4/4)
8. Terminal ileum and cecum; ileocelectomy:
- Metastatic high grade serous carcinoma involving serosa of small and large bowel and 12 of 20 lymph nodes (12/20)
9. Supracolic omentum; excision:
- Metastatic high grade serous carcinoma
10. Soft tissue, right diaphragm; excision:
- Metastatic high grade serous carcinoma
11. Soft tissue, Morrison's pouch; excision:
- Metastatic high grade serous carcinoma
12. Soft tissue, falciform ligament; excision:
- Metastatic high grade serous carcinoma
13. Soft tissue, right hepatic artery; excision:
- Metastatic high grade serous carcinoma
14. Gallbladder; cholecystectomy:
- Metastatic high grade serous carcinoma involving gallbladder serosa
15. Soft tissue, gallbladder fossa; excision:

** Continued on next page **

[page 3 of 4]
- [REDACTED]
- Metastatic high grade serous carcinoma
16. Soft tissue, right liver surface; excision:
- Metastatic high grade serous carcinoma
17. Soft tissue, left diaphragm; excision:
- Metastatic high grade serous carcinoma
18. Lymph nodes, left external iliac; excision:
- Metastatic high grade serous carcinoma involving 2 of 2 lymph nodes (2/2)
19. Lymph nodes, left obturator; excision:
- Metastatic high grade serous carcinoma involving 1 of 4 lymph nodes (1/4)
20. Lymph nodes, left common iliac; excision:
- Three benign lymph nodes (0/3)
21. Lymph nodes, right external iliac; excision:
- Metastatic high grade serous carcinoma involving 1 of 1 lymph node (1/1)
22. Lymph nodes, right obturator; excision:
- Metastatic high grade serous carcinoma involving 1 of 1 lymph node (1/1)
23. Lymph node, right hypogastric; excision:
- One benign lymph node (0/1)
24. Soft tissue, sigmoid mesentery; excision:
- Metastatic high grade serous carcinoma
25. Soft tissue, left paracolic gutter; excision:
- Metastatic high grade serous carcinoma
26. Lymph nodes, small bowel mesentery; excision:
- Metastatic high grade serous carcinoma involving 5 of 5 lymph nodes (5/5)
27. Lymph nodes, aortocaval; excision:
- Metastatic high grade serous carcinoma involving 1 of 1 lymph node (1/1)
28. Lymph nodes, left infra renal; excision:
- Specimen lost in processing
29. Lymph nodes left para-aortic; excision:
- Metastatic high grade serous carcinoma involving 1 of 11 lymph nodes (1/11)
30. Soft tissue, descending colon mesentery; excision:
- Metastatic high grade serous carcinoma
31. Soft tissue, small bowel; excision:

** Continued on next page **

[page 4 of 4]
[REDACTED]

- Metastatic high grade serous carcinoma

32. Soft tissue, terminal ileum; excision:
- Metastatic high grade serous carcinoma involving small bowel serosa and mesentery
33. Colon, proximal margin; excision:
- Benign segment of colon
34. Colon, distal margin; excision:
- Benign segment of colon
35. Soft tissue, umbilicus; excision:
- Metastatic high grade serous carcinoma
36. Lymph nodes, right inguinal; excision:
- Metastatic high grade serous carcinoma involving 2 of 3 lymph nodes (2/3)
37. Lymph nodes, left inguinal; excision:
- Two benign lymph nodes on representative section (0/2)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]
*** Report Electronically Signed Out *** [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 89a7165f-4a60-4ed7-a9af-cdf08756a175 (TCGA-13-A5FU.81DED60F-76BC-47E8-A15C-4488C6FDA1A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).